Somatic mutation profile of tumor specimen MP2PRT-PAPWGV-TMP1-A (aliquot MP2PRT-PAPWGV-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPWGV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,109 days).
Specimen MP2PRT-PAPWGV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46bf3ed3-0d60-4a00-a2fb-d5665cc0dd87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWGV-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWGV-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0af38ec-23f8-4fec-a696-c0788651c2b8

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.*22C>G | 3'UTR (SNP) | VAF 21/37 reads (57%) | catalogued as rs104894362, CM070970, COSV55666258, COSV56095155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASRGL1 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756229723, COSV57126081; called by muse, mutect2, varscan2
- CCDC141 | c.2816C>T p.A939V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1051525524, COSV55381560; called by muse, mutect2, varscan2
- CCT8L2 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 22/479 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63461825, COSV63461841; called by muse, mutect2
- CNTNAP4 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as rs1245559508, COSV100269286; called by muse, mutect2, varscan2
- CREBRF | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs761622677; called by muse, mutect2, varscan2
- NPIPB6 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 182/703 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs927989184; called by muse, mutect2, varscan2
- OR5C1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 171/447 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV65455998; called by muse, mutect2, varscan2
- DENND1C | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 269/595 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- DNAH8 | c.9305C>T p.A3102V | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ITGAD | c.1750G>T p.G584W | Missense Mutation (SNP) | VAF 85/429 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MZF1 | c.2084C>T p.T695M | Missense Mutation (SNP) | VAF 22/574 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); called by muse, mutect2
- OR9H1P | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIWIL1 | c.1150C>G p.P384A | Missense Mutation (SNP) | VAF 55/418 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- RNF34 | c.1505G>C p.R502T | Missense Mutation (SNP) | VAF 174/457 reads (38%) | PolyPhen benign (0.124); called by muse, mutect2, varscan2
- WWC3 | c.1190T>A p.L397H | Missense Mutation (SNP) | VAF 240/646 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DIP2B | c.2016G>C p.T672= | Silent (SNP) | VAF 166/326 reads (51%) | called by muse, mutect2, varscan2
- EXOC3L2 | c.2397G>A p.R799= | Silent (SNP) | VAF 24/516 reads (5%) | called by muse, mutect2
- KCND3 | c.318G>A p.P106= | Silent (SNP) | VAF 159/431 reads (37%) | catalogued as rs770807162, COSV56178260; called by muse, mutect2, varscan2
- SHPRH | c.4557G>A p.L1519= (on ENST00000275233 / NM_001042683.3; = p.L1523= on NM_173082.3) | Silent (SNP) | VAF 59/364 reads (16%) | catalogued as COSV51616949; called by muse, mutect2, varscan2
- UPF3B | c.150G>C p.L50= | Silent (SNP) | VAF 21/444 reads (5%) | called by muse, mutect2
